Gene-level copy-number profile of tumor specimen TCGA-04-1360-01A from TCGA case TCGA-04-1360, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-04-1360-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.64f9f41e-43ea-4193-a30d-3dd6b7863800.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1360-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba5f777f-0de6-4ef7-819a-d8e7eed08af7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,841; copy number 2: 20,216; copy number 3: 14,905; copy number 4: 11,423; copy number 5: 5,177; copy number 6: 2,877; copy number 7: 274; copy number 8: 34; copy number 9: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1360-01A-01D-0452-01): tumor purity 0.8, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:4,774,526–4,775,408, 1 gene: CDYL-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,427 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,468,496–165,356,715, 19 genes, copy number 5 (within-gene range 4–5): RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1.
- chr1:222,557,902–248,919,946, 651 genes, copy number 5–6 (broad region; genes not listed).
- chr2:164,492,417–198,572,581, 484 genes, copy number 5 (broad region; genes not listed).
- chr3:109,225,129–172,523,475, 1,086 genes, copy number 5–6 (broad region; genes not listed).
- chr4:19,098,199–22,819,575, 28 genes, copy number 5 (within-gene range 3–5): AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6.
- chr5:58,198–20,575,873, 354 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:165,129,307–168,264,157, 18 genes, copy number 5 (within-gene range 4–5): AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1.
- chr6:167,607–4,955,551, 108 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr6:4,979,072–21,232,404, 247 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:90,466,424–91,210,590, 1 gene, copy number 5 (within-gene range 2–5): CDK14.
- chr7:90,590,619–159,233,377, 1,408 genes, copy number 5 (broad region; genes not listed).
- chr8:61,785,047–145,066,685, 1,298 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:42,408,168–43,606,251, 41 genes, copy number 5 (within-gene range 4–5): CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3, CAP1P2.
- chr10:48,009,873–52,772,784, 84 genes, copy number 5 (broad region; genes not listed).
- chr10:53,458,197–95,595,372, 711 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr10:101,701,994–102,743,492, 35 genes, copy number 5 (within-gene range 4–5): AC010789.1, FGF8, NPM3, OGA, KCNIP2-AS1, KCNIP2, ARMH3, Metazoa_SRP, Y_RNA, HPS6, AL500527.1, AL500527.2, LDB1, PPRC1, NOLC1, ELOVL3, PITX3, GBF1, NFKB2, PSD, FBXL15, CUEDC2, MIR146B, RPARP-AS1, C10orf95, MFSD13A, ACTR1A, AL121928.1, SUFU, RPL23AP58, RNU6-43P, AL391121.1, TRIM8, ARL3, SFXN2.
- chr12:66,767–34,249,958, 850 genes, copy number 6–8 (broad region; genes not listed).
- chr12:114,238,970–115,364,745, 21 genes, copy number 5: LINC02459, TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2.
- chr12:125,958,688–128,123,103, 57 genes, copy number 5 (within-gene range 4–5): LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC025160.1, AC087894.3, AC087894.2, AC087894.1, LINC02393, LINC00507, LINC00508, LINC02441, AC140121.1, LINC02369, LINC02368.
- chr15:66,931,537–101,933,350, 904 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr18:27,225,742–30,414,073, 22 genes, copy number 5: LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F.

Autosomal genes at a single copy (total copy number 1): 2,420. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
